Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1A7, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1A7-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT**Patient Name:****Med. Rec. #:**

DOB: (Age: 67)

Gender: F

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

Bladder cancer.

Specimens Submitted:

1: SP: Lymph nodes, right common iliac, dissection

2: SP: Lymph nodes, left common iliac, dissection

3: SP: Lymph nodes, right distal pelvic, dissection

4: SP: Lymph nodes, left distal pelvic, dissection

5: SP: Bladder, uterus, cervix, anterior vaginal wall, bilateral fallopian tubes and ovaries, perivesical lymph nodes, urethra, radical cystectomy and hysterectomy

6: SP: Lymph nodes, presacral, dissection

7: SP: Left distal ureter, excision

8: SP: Right distal ureter, excision

DIAGNOSIS:**1. SP: Lymph nodes, right common iliac, dissection:**

Lymph Node Dissection:

Metastatic urothelial carcinoma

Number of lymph nodes examined: 8

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 0.25cm.

Size of the largest metastatic focus: 0.18 cm.

Extranodal extension is not identified

2. SP: Lymph nodes, left common iliac, dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 2

3. SP: Lymph nodes, right distal pelvic, dissection:

Lymph Node Dissection:

Metastatic urothelial carcinoma

Number of lymph nodes examined: 6

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 1.2cm.

Size of the largest metastatic focus: 0.1 cm.

Extranodal extension is not identified

4. SP: Lymph nodes, left distal pelvic, dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 8

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

5. SP: Bladder, uterus, cervix, anterior vaginal wall, bilateral fallopian tubes and ovaries, perivesical lymph nodes, urethra, radical cystectomy and hysterectomy:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Flat (in situ carcinoma)

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

The invasive tumor is primarily in the trigone and bladder neck area.

Bladder Local Invasion:

Perivesical soft tissues

Tumor involves the vesicle-vaginal soft tissue

Extravesical Tumor Extension:

Right ureter involved

Left ureter involved

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Tumor present at right ureteral margin

Tumor present at left ureteral margin

See part 7 and 8

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Exhibiting erosive cystitis

Female Genital Organs:

Show no pathologic abnormalities

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

6. SP: Lymph nodes, presacral, dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

7. SP: Left distal ureter, excision:

Ureter involved with urothelial carcinoma in situ.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Margin is involved with carcinoma.

8. SP: Right distal ureter, excision:

Ureter involved with urothelial carcinoma in situ.
Margin is involved with carcinoma.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out **

Gross Description:

1). The specimen is received , fresh labeled "right common iliac lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.1 to cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes
FAT - remainder of the specimen

2). The specimen is received fresh, labeled "left common iliac lymph nodes" and consists of 2 pink tan firm lymph nodes 0.4 and 1.2 cm. All identified lymph nodes are submitted.

Summary of sections:

BLN - bisected lymph nodes
FAT - remainder of the specimen

3). The specimen is received fresh, labeled "right distal pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes

4). The specimen is received fresh in, labeled "left distal pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 2.0 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes

5). The specimen is received fresh, labeled "bladder, uterus, cervix, anterior vaginal wall, bilateral fallopian tubes and ovaries, perivesicular lymph nodes, urethra". It consists of a bladder with uterus and a portion of vagina measuring 13 cm from superior to inferior, 11 cm laterally and 3.5 cm from anterior to posterior. The bladder measures 8 x 5 x 4 cm, the uterus measures 6 x 3.5 x 1.5 cm, the right ovary measures 2 x 1 x 0.3 cm, the right fallopian tube measures 4.5 cm, the left ovary measures 2 x 1 x 0.6 cm, and the left fallopian tube measures 5 cm. The portion of vaginal cuff measures 4.5 x 2.5 cm. The distal urethra and the vaginal cuff margin are shaved and submitted. The ureteric stumps measure 3.5 cm and show no abnormalities. The specimen is inked blue anteriorly and black posteriorly, and the bladder is opened anteriorly to reveal a tumor measuring 2.2 x 2.2 x 0.3 cm. The lesion is located in the trigone area. The distance from the left and the right ureteric orifices are 0.3 cm and 0.8 cm respectively. On sectioning, the tumor extends to a depth of 1.1 cm and extends into the perivesical fat grossly. The remaining bladder mucosa is

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

unremarkable. Discrete perivesical lymph nodes are not identified. The uterus is bivalved to reveal unremarkable endometrial cavity; endometrium appears to be atrophic. Tissue is submitted for TPS. Gross photographs are taken. Representative sections are submitted.

Summary of sections:

UTHM - distal urethra
RUM - right ureter margin
LUM - left ureter margin
L - lesion
RUO - right ureteric orifice
LUO - left ureteric orifice
PL - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
TRI - trigone
DOME - dome
F - perivesical fat
EMM - endomyometrium
CX - cervix
DVM - distal vaginal margin
RTO - right tube and ovary
LTO - left tube and ovary

6). The specimen is received fresh, labeled "presacral lymph nodes" and consists of two pink tan firm lymph nodes measuring 0.2 and 0.3 cm. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes
FAT - remainder of the specimen

7). The specimen is received in formalin labeled " Left distal ureter, (unclipped end is the margin)." It consists of a segment of ureter measuring 2.0 cm in length and 0.3 cm in diameter. There is a clip on one end of the specimen. The specimen is serially sectioned from the tip with the clip to the non-clipped end and submitted entirely.

Summary of sections:

TC-tip with clip
SS-serial sections from clipped to non-clipped end
TWC-Tip without clip

8). The specimen is received in formalin labeled " Right distal ureter, unclipped end is the margin." It consists of a segment of ureter measuring 2.0 cm in length and 0.6 cm in diameter. There is a clip on one end of the specimen. The specimen is serially sectioned from the tip with the clip to the non-clipped end and submitted entirely.

Summary of sections:

TC-tip with clip
SS-serial sections from clipped to non-clipped end
TWC-Tip without clip

Summary of Sections:

Part 1: SP: Lymph nodes, right common iliac, dissection

Block	Sect. Site	PCs
2	BLN	3
1	FAT	2
1	LN	2

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Part 2: SP: Lymph nodes, left common iliac, dissection

Block	Sect. Site	PCs
2	BLN	3
1	FAT	2

Part 3: SP: Lymph nodes, right distal pelvic, dissection

Block	Sect. Site	PCs
3	BLN	4
1	LN	2

Part 4: SP: Lymph nodes, left distal pelvic, dissection

Block	Sect. Site	PCs
5	BLN	6
1	LN	2

Part 5: SP: Bladder, uterus, cervix, anterior vaginal wall, bilateral fallopian tubes and ovaries, perivesical lymph nodes, urethra, radical cystectomy and hysterectomy

Block	Sect. Site	PCs
1	CX	2
2	DOM	3
1	DVM	2
2	EMM	3
2	F	3
4	L	5
2	LA	3
1	LTO	2
1	LUM	2
1	LUO	2
2	PL	3
2	RA	3
2	RP	3
1	RTO	2
1	RUM	2
1	RUO	2
2	TRI	3
1	UTHM	2

Part 6: SP: Lymph nodes, presacral, dissection

Block	Sect. Site	PCs
1	FAT	2
1	LN	2

Part 7: SP: Left distal ureter, excision

Block	Sect. Site	PCs
1	ss	1
1	tc	1
1	twc	1

Part 8: SP: Right distal ureter, excision

Block	Sect. Site	PCs
1	ss	1
1	tc	1
1	twc	1

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

[Signature]

Source: NCI Genomic Data Commons file c9d6b6d0-b000-41d8-b3e8-df07e57a16d4 (TCGA-DK-A1A7.B64F829C-9624-4F01-BD7A-9E223D81BEE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).